Gene-level copy-number profile of tumor specimen TCGA-AG-A015-01A from TCGA case TCGA-AG-A015, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.3 years (23,496 days).
Specimen TCGA-AG-A015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.2590b231-86ae-4ca0-b815-8af9c376b6c1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A015-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b27718e-b6f0-4cf7-bba0-b7cf1b3a5e30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 35; copy number 2: 40,064; copy number 3: 15,581; copy number 4: 2,716; copy number 5: 1,304.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A015-01A-01D-A003-01): tumor purity 0.87, ploidy 2.39, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,304 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:100,609,601–100,695,479, 3 genes, copy number 5: ADGRG7, AC069223.1, GMFBP1.
- chr13:18,467,172–59,480,132, 755 genes, copy number 5 (broad region; genes not listed).
- chr13:60,322,591–74,444,735, 118 genes, copy number 5 (broad region; genes not listed).
- chr13:78,761,175–98,610,876, 196 genes, copy number 5 (broad region; genes not listed).
- chr13:98,793,429–109,731,700, 138 genes, copy number 5 (broad region; genes not listed).
- chr13:110,613,082–114,337,626, 94 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
